Gene-level copy-number profile of tumor specimen TCGA-LN-A4MR-01A from TCGA case TCGA-LN-A4MR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.9 years (21,142 days).
Specimen TCGA-LN-A4MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ecdd6276-b45c-47ca-a0e4-db64df0a6bee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4MR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/faa468da-3047-42c0-a5a5-778528162f2a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 38; copy number 2: 901; copy number 3: 17,719; copy number 4: 21,868; copy number 5: 5,622; copy number 6: 8,079; copy number 7: 554; copy number 8: 421; copy number 9: 2,157; copy number 10: 637; copy number 11: 1,294; copy number 12: 9; copy number 13: 340; copy number 14: 56; copy number 22: 39; copy number 30: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4MR-01A-11D-A28A-01): tumor purity 0.5, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:154,928,460–154,952,188, 1 gene: PAXIP1-AS2.
- chr7:154,951,226–154,957,107, 2 genes: AC093726.1, AC093726.2.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,596 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,503,948–248,919,946, 928 genes, copy number 9 (broad region; genes not listed).
- chr3:156,809,551–162,601,792, 88 genes, copy number 11 (broad region; genes not listed).
- chr3:188,941,715–190,122,437, 9 genes, copy number 12 (within-gene range 5–12): TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2.
- chr5:58,198–45,895,970, 710 genes, copy number 10–14 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 11 (broad region; genes not listed).
- chr8:27,010,486–27,087,783, 5 genes, copy number 10: AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2.
- chr8:109,573,978–145,066,685, 542 genes, copy number 9–10 (within-gene range 3–10) (broad region; genes not listed).
- chr11:68,683,779–83,423,516, 382 genes, copy number 9–30 (broad region; genes not listed).
- chr11:83,643,602–83,815,263, 3 genes, copy number 9: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr12:66,767–34,249,958, 850 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
